RC case RC-B60S — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/382f0cfa-3593-478e-9cc4-22cdc422b9c1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1958; Vital status: Dead; Days to death: 1,133 days (3.1 years); Year of death: 2017; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (3)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 55.3 years (20,204 days); Year of diagnosis: 2014; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Inguinal / Lymph node, NOS / Lymph Node, Mediastinal / Lymph Node, Retroperitoneal / Lymph Node, Supraclavicular / Bone marrow / Parotid gland / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 2.4 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: EPOCH; Days to treatment start: 14 days; Days to treatment end: 117 days; Number of cycles: 4; Treatment outcome: Progressive Disease; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin; Initial disease status: Initial Diagnosis; Days to treatment start: 134 days; Days to treatment end: 169 days; Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Other; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Romidepsin; Initial disease status: Initial Diagnosis; Days to treatment start: 181 days; Days to treatment end: 243 days; Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bendamustine; Initial disease status: Initial Diagnosis; Days to treatment start: 286 days; Days to treatment end: 315 days; Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Romidepsin; Initial disease status: Initial Diagnosis; Days to treatment start: 341 days; Days to treatment end: 377 days (1.0 years); Number of cycles: 1; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ipilimumab + Nivolumab; Initial disease status: Initial Diagnosis; Days to treatment start: 408 days (1.1 years); Days to treatment end: 729 days (2.0 years); Treatment outcome: Progressive Disease; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclosporine; Initial disease status: Initial Diagnosis; Days to treatment start: 965 days (2.6 years); Days to treatment end: 988 days (2.7 years); Treatment outcome: Progressive Disease; Reason treatment ended: Adverse Event; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclosporine + Cytarabine + Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 1,003 days (2.7 years); Days to treatment end: 1,026 days (2.8 years); Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Adverse Event; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Initial Diagnosis; Days to treatment start: 1,033 days (2.8 years); Days to treatment end: 1,076 days (2.9 years); Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Cytarabine; Initial disease status: Initial Diagnosis; Days to treatment start: 1,098 days (3.0 years); Days to treatment end: 1,110 days (3.0 years); Number of cycles: 1; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dexamethasone + Lenalidomide; Initial disease status: Initial Diagnosis; Days to treatment start: 1,120 days (3.1 years); Days to treatment end: 1,133 days (3.1 years); Number of cycles: 1; Treatment outcome: Progressive Disease; Reason treatment ended: Death; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Treatment given: Treatment type: Stem Cell Transplantation, NOS.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous.
2. Mantle cell lymphoma (Includes all variants blastic, pleomorphic, small cell): ICD-O-3 morphology code: 9673/3; Tissue or organ of origin: Bone marrow; Laterality: Bilateral; Classification of tumor: Prior primary; Age at diagnosis: 48.2 years (17,591 days); Year of diagnosis: 2007; Days to diagnosis: -2,613 days (-7.2 years); AJCC staging edition: 6th; AJCC pathologic stage: Stage IV.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Dexamethasone + Doxorubicin + Vincristine; Regimen or line of therapy: HyperCVAD; Days to treatment start: -2,604 days (-7.1 years); Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Rituximab; Days to treatment start: -2,604 days (-7.1 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
3. Mantle cell lymphoma (Includes all variants blastic, pleomorphic, small cell): ICD-O-3 morphology code: 9673/3; Laterality: Bilateral; Classification of tumor: Synchronous primary; Age at diagnosis: 52.5 years (19,167 days); Year of diagnosis: 2011; Days to diagnosis: -1,037 days (-2.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Lenalidomide + Ofatumumab; Days to treatment start: -972 days (-2.7 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Day 1,117 (end of treatment course 1): Disease response: With Tumor; Imaging type: PET; Imaging result: Positive.
- Follow-up contact recording only the day: day 1,120.

Molecular and laboratory tests
- Lactate Dehydrogenase 268 U/L [Blood test normal range upper: 192].
- Epstein-Barr Virus (ISH): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hematologic Disorder, NOS / Skin Rash.
- Timepoint category: Initial Diagnosis; Weight: 103.3 kg; Height: 188.2 cm; BMI: 29.2.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B60S-NM1-A: Tissue type: Normal; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
- Sample RC-B60S-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B60S-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
